Somatic mutation profile of tumor specimen MBCProject_3876_T1_WES (aliquot MBCProject_3876_T1_WES_1) from CMI case MBCProject_3876, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 40.8 years (14,907 days).
Specimen MBCProject_3876_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e8389f7-4e10-4740-bcd4-50acf202939e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_3876_SALIVA (Saliva), aliquot MBCProject_3876_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27be4d4c-67d3-4d1d-8dcb-086fa2592d53

The open-access MAF lists 101 somatic variants for this specimen: 66 protein-altering or splice-affecting, 26 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 26, Nonsense Mutation 5, In Frame Del 3, 5'Flank 2, RNA 2, 3'UTR 2, 5'UTR 2, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DISP3 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV99608282; called by muse, mutect2, varscan2
- DNAI3 | c.1498G>A p.V500I | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.411); catalogued as rs757993232; called by muse, varscan2
- DOK5 | c.640C>G p.R214G | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs746485155; called by muse, varscan2
- GLS2 | c.584G>C p.G195A | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.329); catalogued as COSV61738029; called by muse, mutect2
- HMCN1 | c.6674C>G p.P2225R | Missense Mutation (SNP) | VAF 61/277 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.938); catalogued as COSV54903839; called by muse, mutect2, varscan2
- KCNH2 | c.2115G>T p.W705C | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD150035; called by muse, mutect2, varscan2
- LZTS1 | c.1516C>T p.R506W | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs759721425, COSV56116114; called by mutect2, varscan2
- NAT10 | c.25C>T p.R9* | Nonsense Mutation (SNP) | VAF 33/183 reads (18%) | catalogued as rs756936856, COSV57664089; called by muse, mutect2, varscan2
- OR4K1 | c.317G>T p.S106I | Missense Mutation (SNP) | VAF 24/351 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV53460739; called by muse, mutect2
- RYR2 | c.6298C>T p.R2100W | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs753164125, COSV63679185, COSV63688704; ClinVar: uncertain significance; called by muse, mutect2
- STAT6 | c.2126A>G p.E709G | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs371752088; called by muse, mutect2
- TECTA | c.4497C>A p.D1499E | Missense Mutation (SNP) | VAF 34/187 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760726137, CM161544, COSV50801591; called by muse, mutect2, varscan2
- WDR43 | c.964C>A p.P322T | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs764602166; called by muse, mutect2, varscan2
- ZCCHC14 | c.1169C>T p.S390L (on ENST00000268616; = p.S527L on NM_015144.3) | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as rs752742696, COSV99234613; called by muse, varscan2
- ABCA13 | c.7630_7641del p.F2544_N2547del | In Frame Del (DEL) | VAF 19/200 reads (10%) | called by mutect2, pindel
- AGBL1 | c.3017G>C p.R1006T | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, varscan2
- ALDH8A1 | c.644G>T p.G215V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ANO6 | c.1716del p.F572Lfs*6 | Frame Shift Del (DEL) | VAF 31/231 reads (13%) | called by mutect2, pindel, varscan2
- ASPH | c.2185C>A p.Q729K | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- BCORL1 | c.4949C>T p.T1650I | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.132); called by muse, mutect2
- BIRC5 | c.149A>G p.N50S | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- BNIP5 | c.176C>G p.S59* | Nonsense Mutation (SNP) | VAF 11/85 reads (13%) | called by muse, mutect2, varscan2
- CACTIN | c.1421T>G p.V474G | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- CEMP1 | c.302C>A p.P101H | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- CWH43 | c.388C>G p.Q130E | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.023); called by muse, mutect2
- DGKI | c.1183C>A p.Q395K | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); called by muse, mutect2
- DNAH7 | c.9322G>T p.E3108* | Nonsense Mutation (SNP) | VAF 28/124 reads (23%) | called by muse, mutect2, varscan2
- EHD2 | c.1368C>G p.I456M | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- ERCC4 | c.1039_1041del p.P347del | In Frame Del (DEL) | VAF 16/126 reads (13%) | called by pindel, varscan2
- EVX2 | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 25/237 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- FASTKD2 | c.49A>G p.M17V | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- FOXO6 | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.01); called by muse, mutect2
- FREM3 | c.2074A>C p.T692P | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- FREM3 | c.1826A>T p.Y609F | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.83); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- GJA3 | c.356G>T p.S119I | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2
- HMCN2 | c.9222G>A p.W3074* | Nonsense Mutation (SNP) | VAF 11/89 reads (12%) | called by muse, mutect2, varscan2
- JMJD1C | c.3574T>A p.S1192T | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- JUN | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.124); called by muse, mutect2
- KLF12 | c.911G>T p.R304I | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.134); called by muse, mutect2
- MIS18BP1 | c.2535G>T p.K845N | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.071); called by muse, mutect2
- MMP19 | c.203T>G p.V68G | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- MYOT | c.142A>T p.T48S | Missense Mutation (SNP) | VAF 32/266 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- NCKAP5L | c.220C>G p.L74V | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NFIA | c.1501C>G p.Q501E | Missense Mutation (SNP) | VAF 19/229 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.894); called by muse, mutect2
- NSUN7 | c.1742C>T p.S581L | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- NT5DC4 | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 11/63 reads (17%) | called by muse, mutect2, varscan2
- OR4C13 | c.96C>G p.I32M | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- PHF14 | c.2519_2532+1del | In Frame Del (DEL) | VAF 10/104 reads (10%) | called by mutect2, pindel
- PHLDB2 | c.1278G>A p.M426I | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- PKD1L2 | c.525G>T p.Q175H | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.145); called by muse, mutect2
- RIMS1 | c.2206A>C p.K736Q | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RRS1 | c.791A>T p.E264V | Missense Mutation (SNP) | VAF 40/278 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RUFY2 | c.874C>A p.Q292K | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- SDE2 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2
- SEMA7A | c.1515G>T p.M505I | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.55); called by muse, mutect2
- SLFN14 | c.1138C>A p.P380T | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- SUN3 | c.1055C>G p.T352R | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.057); called by muse, mutect2
- SUPT6H | c.1449A>T p.K483N | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); called by muse, mutect2
- SUSD5 | c.767G>T p.G256V | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- TAB3 | c.1886A>T p.K629I | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTN | c.23408C>G p.P7803R (on ENST00000591111; = p.P6876R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/188 reads (11%) | PolyPhen benign (0.045); called by muse, mutect2
- TUT4 | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP34 | c.9196C>A p.L3066I | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT tolerated (0.95); PolyPhen probably damaging (0.931); called by muse, varscan2
- VCAN | c.4948G>C p.D1650H | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- ZBTB12 | c.677C>G p.P226R | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- ZNF479 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- AC013489.1 | c.885C>G p.L295= | Silent (SNP) | VAF 16/145 reads (11%) | catalogued as COSV51551015; called by muse, mutect2, varscan2
- ATP8B3 | c.3636A>T p.P1212= | Silent (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
- BTBD18 | c.381T>G p.G127= | Silent (SNP) | VAF 14/79 reads (18%) | called by muse, mutect2, varscan2
- C4orf54 | c.2655C>T p.G885= | Silent (SNP) | VAF 15/105 reads (14%) | catalogued as rs1413266077; called by muse, mutect2, varscan2
- CACNA1F | c.2112C>T p.V704= | Silent (SNP) | VAF 17/90 reads (19%) | called by muse, mutect2, varscan2
- CASP5 | c.90G>T p.V30= | Silent (SNP) | VAF 27/168 reads (16%) | called by muse, mutect2, varscan2
- DAZAP1 | c.975G>A p.P325= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs373096733; called by mutect2, varscan2
- DOCK6 | c.3267G>A p.P1089= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as rs567514358, COSV53921664; called by muse, mutect2, varscan2
- GK2 | c.171T>A p.P57= | Silent (SNP) | VAF 11/63 reads (17%) | called by muse, mutect2, varscan2
- GLUL | c.492T>A p.G164= | Silent (SNP) | VAF 75/627 reads (12%) | called by muse, mutect2, varscan2
- IL31RA | c.2010G>C p.G670= | Silent (SNP) | VAF 18/168 reads (11%) | called by muse, varscan2
- LPO | c.528C>T p.F176= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV51858221, COSV51861894; called by muse, mutect2, varscan2
- LRRN1 | c.75T>C p.S25= | Silent (SNP) | VAF 13/126 reads (10%) | called by muse, mutect2, varscan2
- MTMR6 | c.543G>T p.R181= | Silent (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2, varscan2
- NUP58 | c.1099C>T p.L367= | Silent (SNP) | VAF 15/148 reads (10%) | catalogued as rs1356571353; called by muse, mutect2, varscan2
- ONECUT2 | c.981G>A p.S327= | Silent (SNP) | VAF 11/51 reads (22%) | called by muse, mutect2
- OSBPL11 | c.1005A>G p.L335= | Silent (SNP) | VAF 33/256 reads (13%) | called by muse, mutect2, varscan2
- PLVAP | c.903C>T p.N301= | Silent (SNP) | VAF 18/129 reads (14%) | catalogued as rs1469607810; called by muse, mutect2, varscan2
- RHOXF2B | c.306C>A p.G102= | Silent (SNP) | VAF 24/343 reads (7%) | called by muse, mutect2
- RING1 | c.435A>T p.L145= | Silent (SNP) | VAF 19/186 reads (10%) | called by muse, mutect2
- SACS | c.1506C>G p.P502= | Silent (SNP) | VAF 32/214 reads (15%) | called by muse, mutect2, varscan2
- SBF1 | c.2184T>C p.S728= | Silent (SNP) | VAF 11/104 reads (11%) | called by mutect2, varscan2
- SERPINF2 | c.1080C>T p.F360= | Silent (SNP) | VAF 8/79 reads (10%) | called by muse, mutect2, varscan2
- SKAP1 | c.672G>A p.E224= | Silent (SNP) | VAF 13/87 reads (15%) | called by muse, mutect2, varscan2
- SOS2 | c.363A>G p.K121= | Silent (SNP) | VAF 10/142 reads (7%) | called by muse, mutect2
- VPS13A | c.2541A>G p.P847= | Silent (SNP) | VAF 19/253 reads (8%) | catalogued as rs930824912; ClinVar: likely benign; called by muse, mutect2
- C4orf50 | chr4:5989675 C>G | 5'Flank (SNP) | VAF 13/68 reads (19%) | called by muse, mutect2, varscan2
- CREB3L1 | c.*138_*147del | 3'UTR (DEL) | VAF 7/45 reads (16%) | called by mutect2, pindel
- EPSTI1 | chr13:42888372 G>C | 3'Flank (SNP) | VAF 28/262 reads (11%) | called by muse, mutect2, varscan2
- ETV1 | c.-27G>T | 5'UTR (SNP) | VAF 14/112 reads (13%) | catalogued as rs1175308054; called by mutect2, varscan2
- LINC00239 | n.315A>T | RNA (SNP) | VAF 14/173 reads (8%) | called by muse, mutect2
- LINC00636 | n.190A>G | RNA (SNP) | VAF 22/187 reads (12%) | called by muse, mutect2, varscan2
- NCDN | chr1:35557721 A>C | 5'Flank (SNP) | VAF 31/226 reads (14%) | called by muse, mutect2, varscan2
- UMPS | c.*1384G>A | 3'UTR (SNP) | VAF 7/75 reads (9%) | catalogued as rs1401121770; called by muse, varscan2
- WDR1 | c.-41G>A | 5'UTR (SNP) | VAF 9/32 reads (28%) | called by muse, varscan2
